Gene-level copy-number profile of tumor specimen TCGA-KD-A5QS-01A from TCGA case TCGA-KD-A5QS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Myometrium; Age at diagnosis: 55.9 years (20,410 days).
Specimen TCGA-KD-A5QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.479d61d7-b682-4760-8fea-92b7e52c802a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KD-A5QS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b2226b1-1919-492c-bfd2-6a60aaa30149

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 150; copy number 1: 2,076; copy number 2: 19,546; copy number 3: 16,240; copy number 4: 17,984; copy number 5: 3,105; copy number 6: 671; copy number 7: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KD-A5QS-01A-11D-A27O-01): tumor purity 0.81, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 150 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,193,100–189,475,192, 3 genes: AC107391.1, AC105924.1, HSP90AA4P.
- chr4:189,764,391–190,092,279, 23 genes (within-gene range 0–1): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr10:74,641,410–76,560,994, 37 genes: NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1.
- chr10:87,659,613–88,877,544, 24 genes (within-gene range 0–2): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2.
- chr13:29,764,371–30,429,758, 20 genes (within-gene range 0–2): UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5.
- chr13:31,739,526–32,538,885, 16 genes: RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,389,567–48,711,226, 8 genes (within-gene range 0–1): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.
- chr13:49,247,925–49,633,872, 8 genes (within-gene range 0–1): CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11.
- chr13:50,082,295–50,387,158, 7 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr14:68,113,706–68,149,908, 3 genes: AL133370.2, AL133370.1, RN7SL706P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,801 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:85,442,495–90,005,629, 173 genes, copy number 5 (broad region; genes not listed).
- chr6:43,995,723–44,074,652, 1 gene, copy number 5 (within-gene range 3–5): AL109615.3.
- chr6:44,058,792–49,824,782, 90 genes, copy number 5 (broad region; genes not listed).
- chr6:60,281,444–61,681,049, 9 genes, copy number 5 (within-gene range 3–5): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1.
- chr6:61,870,097–61,893,882, 1 gene, copy number 5: AL355347.1.
- chr7:63,011,463–64,563,075, 91 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:60,914,407–72,874,135, 234 genes, copy number 5 (broad region; genes not listed).
- chr9:120,388,869–127,578,989, 151 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr13:18,467,172–20,723,098, 76 genes, copy number 6 (broad region; genes not listed).
- chr13:44,939,249–47,459,234, 57 genes, copy number 5: NUFIP1, AL359706.1, GPALPP1, RN7SL49P, RN7SKP3, GTF2F2, RN7SKP4, AL138693.1, KCTD4, AL138963.2, TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25, COG3, ERICH6B, RNA5SP27, TIMM9P3, COX4I1P2, LINC01055, AKR1B1P4, CBY2, Metazoa_SRP, SIAH3, ZC3H13, CPB2-AS1, CPB2, LCP1, RN7SL288P, LRRC63, RN7SKP5, ABITRAMP1, AL139801.1, LINC00563, RUBCNL, RNU2-6P, RNU6-68P, PPP1R2P4, LINC01198, AL138686.2, OR7E101P, AL138686.1, COX17P1, FKBP1AP3, LRCH1, AL359880.1, ESD, HTR2A, HTR2A-AS1, GNG5P5, RN7SL700P.
- chr13:69,700,594–81,691,072, 138 genes, copy number 5–7 (broad region; genes not listed).
- chr13:109,269,634–111,115,678, 40 genes, copy number 5: AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2.
- chr13:111,122,652–111,153,171, 3 genes, copy number 5: ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1.
- chr15:91,408,708–95,826,499, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:48,496,990–50,371,480, 50 genes, copy number 5: MOCS1P1, N4BP1, AC026470.2, RPS2P44, AC023813.2, AC023813.1, AC007611.1, AC023813.3, AC023813.4, KLF8P1, RNU6-257P, AC023827.1, MTND4LP25, AC044798.3, AC044798.1, AC044798.2, CBLN1, AC007614.1, AC007614.2, C16orf78, AC007861.1, AC007861.2, LINC02179, ZNF423, ADAM3B, MRPS21P7, AC027348.2, MRPS21P8, AC027348.1, AC007603.2, AC007603.1, RPL34P29, AC007603.3, CNEP1R1, AC007610.1, AC007610.3, Metazoa_SRP, ACTG1P16, HEATR3, AC007610.4, RNY4P3, AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B, ADCY7, MIR6771, BRD7, AC007493.2.
- chr17:9,910,606–22,706,703, 473 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:55,842,677–56,511,659, 3 genes, copy number 5 (within-gene range 3–5): AC090618.1, ANKFN1, AC006600.1.
- chr17:59,859,479–70,629,265, 303 genes, copy number 5–6 (broad region; genes not listed).
- chr17:73,334,384–82,490,537, 408 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:53,480,825–59,386,749, 102 genes, copy number 5 (broad region; genes not listed).
- chr18:59,459,072–59,465,682, 1 gene, copy number 5: AC016229.1.
- chr18:60,495,868–65,652,053, 64 genes, copy number 5 (broad region; genes not listed).
- chr19:4,343,527–24,163,425, 1,039 genes, copy number 5 (broad region; genes not listed).
- chr20:58,459,101–64,242,253, 196 genes, copy number 5 (broad region; genes not listed).
- chr22:27,204,211–28,679,865, 26 genes, copy number 5 (within-gene range 3–5): AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 2,076. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
